TCGA case TCGA-AA-3692 — Colon Adenocarcinoma (TCGA-COAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Colon; Tissue source site: Indivumed. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/bce3ce45-4fb3-4d8e-9ec7-d24427c2ba4d

Demographics
Sex at birth: female; Country of residence at enrollment: Germany; Age at index: 47 years; Vital status: Dead; Days to death: 1,095 days (3.0 years).

Diagnoses (3)
1. Mucinous adenocarcinoma (the primary disease): ICD-O-3 morphology code: 8480/3; ICD-10 code: C18.9; Tissue or organ of origin: Colon, NOS; Site of resection or biopsy: Splenic flexure of colon; Classification of tumor: primary; Age at diagnosis: 47.0 years (17,167 days); Year of diagnosis: 2008; AJCC staging edition: 6th; AJCC pathologic T: T3; AJCC pathologic N: N2; AJCC pathologic M: M1; AJCC pathologic stage: Stage IV; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Residual disease: R2; Days to last follow up: 1,095 days (3.0 years).
   Pathology details: Lymph nodes positive: 5; Lymph nodes tested: 30; Lymphatic invasion present: No; Vascular invasion present: No.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Bevacizumab; Days to treatment start: 31 days; Days to treatment end: 669 days (1.8 years); Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil + Leucovorin Calcium; Days to treatment start: 31 days; Days to treatment end: 669 days (1.8 years); Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Irinotecan; Days to treatment start: 31 days; Days to treatment end: 883 days (2.4 years); Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 31 days; Days to treatment end: 426 days (1.2 years); Treatment dose: 39 Gy; Treatment outcome: Progressive Disease; Treatment anatomic sites: Distant Site.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 365 days (1.0 years); Days to treatment end: 761 days (2.1 years); Treatment dose: 38 Gy; Treatment outcome: Progressive Disease; Treatment anatomic sites: Distant Site.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Cetuximab; Days to treatment start: 883 days (2.4 years); Days to treatment end: 883 days (2.4 years); Treatment outcome: Progressive Disease.
2. Carcinoma in situ, NOS: ICD-O-3 morphology code: 8010/2; Tissue or organ of origin: Rectum, NOS; Classification of tumor: Synchronous primary.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
3. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 48.1 years (17,563 days); Days to diagnosis: 396 days (1.1 years); Prior treatment: Yes.
   Recorded as not given: Surgery, NOS.

Follow-up (3 entries)
- Days to follow up: 0 days; Disease response: With Tumor.
- Day 396 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 396 days (1.1 years).
- Days to follow up: 1,095 days (3.0 years); Disease response: With Tumor.

Molecular and laboratory tests
- CEA: 49.21 ng/mL.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Comorbidities: Colon Polyps; Risk factors: Colon Polyps.

Family history
- Relative with cancer history: no.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-AA-3692-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 0.6; Intermediate dimension: 0.6; Shortest dimension: 0.3.
  Slide TCGA-AA-3692-01A-01-BS1: Section location: Bottom; Percent tumor cells: 79; Percent tumor nuclei: 70; Percent normal cells: 5; Percent necrosis: 8; Percent stromal cells: 8.
  Slide TCGA-AA-3692-01A-01-TS1: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 70; Percent normal cells: 10; Percent necrosis: 5; Percent stromal cells: 15.
- Sample TCGA-AA-3692-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Samples TCGA-AA-3692-10A, TCGA-AA-3692-10B (2 with the same recorded description): Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Colon Mucinous Adenocarcinoma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Anatomic organ subdivision: Splenic Flexure; Lymph nodes examined: Yes; CEA level pretreatment: 49.21; Lymphovascular invasion indicator: No; KRAS gene analysis indicator: No; BRAF gene analysis indicator: No; History colon polyps: Yes; Mismatch rep proteins tested by IHC: No.
- Drug treatment 1: Pharmaceutical therapy drug name: Folinic acid; Treatment best response: Clinical Progressive Disease.
- Drug treatment 2: Pharmaceutical therapy drug name: 5-Fluorouracil; Treatment best response: Clinical Progressive Disease.
- Radiation treatment 1: Treatment best response: Radiographic Progressive Disease.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor; New tumor event diagnosis indicator: Yes.
- Follow-up form, New tumor event: New tumor event surgery: No.
- Other malignancy form: Malignancy type: Synchronous Malignancy; Other malignancy anatomic site: Rectum; Other malignancy histological type: Carcinoma in situ of other and unspecified digestive organs.

GDC annotations on this case (curator notes; quoted as recorded):
- Synchronous malignancy: Synchronous malignancy of the rectum.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,095 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,095 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 396 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-AA-3692-01A-01D-0903-01): tumor purity 0.82, ploidy 1.96, whole-genome doublings 0.
